Somatic mutation profile of tumor specimen TCGA-BP-5178-01A (aliquot TCGA-BP-5178-01A-01D-1429-08) from TCGA case TCGA-BP-5178, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 71.4 years (26,070 days).
Specimen TCGA-BP-5178-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a0005f3-031f-4f08-af6e-b6e3ddc1ae51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5178-11A (Solid Tissue Normal), aliquot TCGA-BP-5178-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55564385-3fbe-4a86-a02c-fa7489412655

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 38/128 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101229406, COSV67960170, COSV67961004; called by muse, mutect2, varscan2
- SETD2 | c.4996T>C p.Y1666H | Missense Mutation (SNP) | VAF 101/256 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57436750; called by muse, mutect2, varscan2
- VHL | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793878, CM042503, CM941389, CM961440, COSV56543194, COSV56543241, COSV56546612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACHE | c.1141_1143del p.N381del | In Frame Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs1294380674; called by mutect2, pindel, varscan2
- ADAMTS20 | c.4637C>T p.S1546L | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV67130679; called by muse, mutect2, varscan2
- AL645922.1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54960432; called by muse, mutect2, varscan2
- B3GNTL1 | c.895A>C p.I299L | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV57948982; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3955G>A p.G1319R | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63244927; called by muse, mutect2, varscan2
- CACNG6 | c.664G>A p.G222S (on ENST00000252729 / NM_145814.1; = p.G151S on NM_031897.2) | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.95); catalogued as COSV53166521; called by muse, mutect2, varscan2
- CELSR1 | c.5574G>A p.M1858I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV53088965; called by muse, mutect2, varscan2
- COPA | c.444C>G p.D148E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375088629; called by muse, mutect2, varscan2
- CPS1 | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51808896; called by muse, mutect2, varscan2
- DIP2A | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs572074409, COSV59476932; called by muse, mutect2, varscan2
- DNAJC18 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57415723; called by muse, mutect2, varscan2
- EPX | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56596245; called by muse, mutect2, varscan2
- GIPR | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV54423841; called by muse, mutect2, varscan2
- GPR148 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs113110453, COSV59308130; called by muse, mutect2, varscan2
- GRIK2 | c.2405A>G p.N802S | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs780159044, COSV59732469; called by muse, mutect2, varscan2
- KHDRBS1 | c.1168A>T p.S390C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV56981868; called by muse, mutect2, varscan2
- KIF26B | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs376166521; called by muse, mutect2
- KLK6 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777841287, COSV100037817, COSV59565159; called by muse, mutect2, varscan2
- LRP1B | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV67212997, COSV67235479; called by muse, mutect2, varscan2
- MED12 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61338651; called by muse, mutect2, varscan2
- NONO | c.795T>G p.Y265* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV52137272; called by muse, mutect2, varscan2
- PCDHGA1 | c.2269G>T p.V757F | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs779897860, COSV65296179; called by muse, mutect2, varscan2
- PKHD1L1 | c.7778A>T p.D2593V | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV65742128; called by muse, mutect2, varscan2
- PLCB1 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV62042026, COSV62048712; called by muse, mutect2, varscan2
- REC114 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV58522500; called by muse, mutect2, varscan2
- RSF1 | c.1614A>C p.E538D | Missense Mutation (SNP) | VAF 86/494 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV57839284; called by muse, mutect2, varscan2
- SBF1 | c.4921C>T p.P1641S | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV62367396; called by muse, mutect2, varscan2
- SCG2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59539814; called by muse, mutect2, varscan2
- SLC35B3 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 17/136 reads (13%) | catalogued as COSV59467985; called by muse, mutect2, varscan2
- TINAGL1 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54698974; called by muse, mutect2, varscan2
- TP63 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53203025; called by muse, mutect2
- TSHZ3 | c.714T>A p.H238Q | Missense Mutation (SNP) | VAF 101/423 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53670282; called by muse, mutect2, varscan2
- TSHZ3 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 101/421 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53670327; called by muse, mutect2, varscan2
- UEVLD | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV55577850; called by muse, mutect2, varscan2
- ZFPM2 | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1215768367, COSV65873392; called by muse, mutect2, varscan2
- ZNF207 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.489); catalogued as rs1371434179, COSV58299734; called by muse, mutect2, varscan2
- ARNTL2 | c.313del p.M105* | Frame Shift Del (DEL) | VAF 64/171 reads (37%) | called by mutect2, pindel, varscan2
- FAM27E5 | n.279G>T | Splice Region (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- MON1B | c.653_655del p.L218del | In Frame Del (DEL) | VAF 33/147 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHG2 | c.2891_2900del p.L964Rfs*79 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | called by mutect2, pindel, varscan2
- RAB6D | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB16 | c.491_510del p.E164Gfs*70 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel
- ADAMTS17 | c.2280A>G p.L760= | Silent (SNP) | VAF 143/516 reads (28%) | catalogued as COSV51479218; called by muse, mutect2, varscan2
- CA5B | c.438C>T p.D146= | Silent (SNP) | VAF 129/219 reads (59%) | catalogued as COSV59416315; called by muse, mutect2, varscan2
- CEP131 | c.2421G>A p.L807= (on ENST00000269392 / NM_001319228.2; = p.L804= on NM_014984.4) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53952759; called by muse, mutect2
- FLI1 | c.966C>T p.G322= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs200962985; called by muse, mutect2, varscan2
- PDXDC1 | c.1647G>T p.L549= | Silent (SNP) | VAF 65/247 reads (26%) | catalogued as COSV55074208; called by muse, mutect2, varscan2
- PRX | c.999G>A p.V333= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52529598, COSV52529722, COSV52534527; called by muse, mutect2, varscan2
- SEMA6A | c.1812G>C p.L604= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV56711024; called by muse, mutect2, varscan2
- SENP7 | c.2148G>T p.L716= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV58611279; called by muse, mutect2, varscan2
- SLC9A5 | c.1255C>T p.L419= | Silent (SNP) | VAF 105/351 reads (30%) | catalogued as COSV55361782; called by muse, mutect2, varscan2
- TOM1L1 | c.880T>C p.L294= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1178624952, COSV61947392; called by muse, mutect2, varscan2
- VPS45 | c.495C>T p.L165= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs782696433, COSV64887628; called by muse, mutect2
- ZRANB1 | c.1524A>G p.A508= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV62842300; called by muse, mutect2, varscan2
